Gene-level copy-number profile of tumor specimen TCGA-22-4604-01A from TCGA case TCGA-22-4604, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.8 years (26,952 days).
Specimen TCGA-22-4604-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.18f66043-ea22-43f5-b423-b6ed91903953.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4604-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e8d5074c-561c-4553-9a71-6138a4ecc2cb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 277; copy number 1: 4; copy number 2: 15,632; copy number 3: 20,309; copy number 4: 15,891; copy number 5: 3,035; copy number 6: 1,365; copy number 7: 1,279; copy number 8: 540; copy number 9: 167; copy number 10: 591; copy number 11: 692; copy number 12: 2; copy number 14: 17; copy number 18: 12.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4604-01A-01D-1195-01): tumor purity 0.84, ploidy 5.39, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 277 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:20,999,509–31,645,160, 132 genes (broad region; genes not listed).
- chr9:37,878,116–43,045,120, 145 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 3,300 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:34,692,820–41,260,096, 124 genes, copy number 8 (broad region; genes not listed).
- chr3:148,028,046–198,222,513, 905 genes, copy number 9–11 (broad region; genes not listed).
- chr5:15,384,220–18,746,173, 72 genes, copy number 7 (broad region; genes not listed).
- chr6:18,522,735–18,674,001, 2 genes, copy number 11 (within-gene range 3–11): MIR548A1HG, MIR548A1.
- chr6:19,290,319–19,321,021, 1 gene, copy number 9: AL357052.1.
- chr6:19,348,181–19,438,418, 2 genes, copy number 9: RPL5P20, RNA5SP205.
- chr9:16,203,935–17,503,923, 13 genes, copy number 12–18: C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:17,589,161–17,591,318, 1 gene, copy number 12: PABPC1P11.
- chr9:19,507,452–20,995,955, 17 genes, copy number 14 (within-gene range 0–14): SLC24A2, C11orf98P1, AL158077.2, AL158077.1, AL591222.1, AL591222.2, AL591222.3, AL512635.1, MLLT3, MIR4473, RNU4-26P, MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B.
- chr9:32,293,558–33,248,567, 28 genes, copy number 8: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1, SMU1, B4GALT1, B4GALT1-AS1, RNU4ATAC15P, SPINK4.
- chr9:35,814,451–35,865,518, 1 gene, copy number 8 (within-gene range 6–8): TMEM8B.
- chr9:35,859,055–37,358,149, 40 genes, copy number 8 (within-gene range 4–8): OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38, MELK, AL442063.1, AL450267.2, MIR4475, PAX5, AL450267.1, MIR4540, MIR4476, AL161781.2, AL161781.1, LINC01400, AL512604.3, EBLN3P, AL512604.2, ZCCHC7, Y_RNA, AL512604.1, Y_RNA.
- chr14:18,333,726–38,948,273, 682 genes, copy number 7–8 (broad region; genes not listed).
- chr18:47,390–9,648,502, 194 genes, copy number 7 (broad region; genes not listed).
- chr18:20,946,906–60,902,726, 593 genes, copy number 7–8 (broad region; genes not listed).
- chr20:87,250–32,277,510, 625 genes, copy number 8–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
